CCG case CUPP-B38V — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/53d71acc-dd37-4846-9905-b3a5926825ca

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Year of birth: 1940; Vital status: Alive.

Diagnoses (6)
1. Squamous cell carcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8070/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 77.5 years (28,320 days); Year of diagnosis: 2018; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: TX; AJCC clinical M: M1; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic M: M1; AJCC pathologic stage: Stage III; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lung, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative.
2. Progression of the lung (histology not recorded by GDC). Age at diagnosis: 77.8 years (28,412 days); Year of diagnosis: 2018; Days to diagnosis: 92 days.
3. Progression of the lymph node (histology not recorded by GDC). Age at diagnosis: 77.8 years (28,412 days); Year of diagnosis: 2018; Days to diagnosis: 92 days.
4. Progression of the liver (histology not recorded by GDC). Age at diagnosis: 77.8 years (28,412 days); Year of diagnosis: 2018; Days to diagnosis: 92 days.
5. Progression of the pleura (histology not recorded by GDC). Age at diagnosis: 77.8 years (28,412 days); Year of diagnosis: 2018; Days to diagnosis: 92 days.
6. Progression of the connective, subcutaneous and other soft tissues (histology not recorded by GDC). Age at diagnosis: 77.8 years (28,412 days); Year of diagnosis: 2018; Days to diagnosis: 92 days.

Follow-up (7 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 40; ECOG performance status: 3.
- Day 92 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 92 days.
- Day 92 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 92 days.
- Day 92 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues, NOS; Days to progression: 92 days.
- Day 92 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 92 days.
- Day 92 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 92 days.
- Days to follow up: 150 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 55 kg; Height: 168 cm; BMI: 19.5.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 60; Tobacco smoking onset year: 1958.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B38V-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen.
- Sample CUPP-B38V-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B38V-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 25; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 55; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
